Somatic mutation profile of tumor specimen 7316UP-109 (aliquot 7316UP-109-1105242) from CPTAC case C229764, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 7316UP-109: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 634369c4-3adc-4610-9694-36647e1a513e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105275 (Blood Derived Normal), aliquot 7316UP-1359-1105275; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bcba428-697c-4d78-865d-d39fc60541e5

The open-access MAF lists 97 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 11, Nonsense Mutation 4, 5'UTR 2, RNA 2, Splice Region 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 134/340 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs368926208; called by muse, mutect2, varscan2
- AK9 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs979267036; called by muse, mutect2, varscan2
- ANO1 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs1292562502, COSV62446092; called by muse, mutect2, varscan2
- BCL11B | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs370505554; called by muse, mutect2, varscan2
- BLCAP | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.298); catalogued as rs775274090, COSV50351105; called by muse, mutect2, varscan2
- BTD | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs397514409, CM0910680; called by muse, mutect2, varscan2
- C3orf38 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371557541; called by muse, mutect2, varscan2
- CFAP46 | c.4588G>A p.V1530I | Missense Mutation (SNP) | VAF 74/104 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63952113; called by muse, mutect2, varscan2
- COL22A1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450144812; called by muse, mutect2, varscan2
- CTH | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 162/619 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61007916; called by muse, mutect2, varscan2
- DDIAS | c.2900C>T p.S967F | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); catalogued as rs754322803; called by muse, mutect2, varscan2
- DHX29 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779803158; called by muse, mutect2, varscan2
- EGFLAM | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.328); catalogued as rs370857999; called by muse, mutect2, varscan2
- EXOC2 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as rs1357029788; called by muse, mutect2, varscan2
- HERC1 | c.13891A>G p.S4631G | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as rs1225644713; called by muse, mutect2, varscan2
- KRT4 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 185/525 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs748322714, COSV53407253, COSV53409475; called by muse, mutect2, varscan2
- KSR2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753606177, COSV60376257; called by muse, mutect2, varscan2
- MINDY4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs759611015; called by muse, mutect2, varscan2
- MMP17 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs538789299; called by muse, mutect2, varscan2
- MUC16 | c.14093C>T p.T4698I | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.685); catalogued as rs371767093; called by muse, mutect2, varscan2
- MYH2 | c.4317G>C p.E1439D | Missense Mutation (SNP) | VAF 112/319 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV55444658; called by muse, mutect2, varscan2
- NDST3 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV56626470; called by muse, mutect2, varscan2
- NLRP8 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs371255067; called by muse, mutect2, varscan2
- OR5B21 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100835082, COSV100835114, COSV64482300; called by muse, mutect2, varscan2
- PCLO | c.5489T>A p.L1830H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428670; called by muse, mutect2, varscan2
- PRKAG3 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 94/199 reads (47%) | catalogued as COSV52100655; called by muse, mutect2, varscan2
- PROKR2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 232/584 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774093318, CM085657, COSV54086301, COSV54089320; called by muse, mutect2, varscan2
- RAPGEFL1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.988); catalogued as rs1334000386; called by muse, mutect2, varscan2
- RTN1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1218288997, COSV50721426; called by muse, mutect2, varscan2
- SPAG11B | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs754937238; called by mutect2, varscan2
- SRGAP2 | c.1705C>T p.R569W (on ENST00000624873 / NM_001170637.4; = p.R570W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480133661; called by muse, mutect2, varscan2
- SUSD4 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377586871; called by muse, mutect2, varscan2
- TEX37 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs577813909; called by muse, varscan2
- THPO | c.424G>C p.E142Q (on ENST00000649095 / NM_001290003.1; = p.E2Q on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 408/674 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52612356; called by muse, mutect2, varscan2
- TNFRSF21 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs148136049; called by muse, mutect2, varscan2
- TTC29 | c.1243T>A p.Y415N | Missense Mutation (SNP) | VAF 82/159 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57279505; called by muse, mutect2, varscan2
- VWA3B | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.526); catalogued as COSV68241271; called by muse, mutect2, varscan2
- ARVCF | c.1908G>A p.M636I | Missense Mutation (SNP) | VAF 102/144 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.1490C>T p.S497L (on ENST00000350061 / NM_001128840.3; = p.S517L on NM_000720.4) | Missense Mutation (SNP) | VAF 105/323 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC17A | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL12A1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREG2 | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CRYBA2 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNS1 | c.280_282del p.D94del | In Frame Del (DEL) | VAF 39/161 reads (24%) | called by pindel, varscan2
- KRT37 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEB4 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MLXIPL | c.379T>G p.W127G | Missense Mutation (SNP) | VAF 74/893 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOBOX | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2
- NT5DC2 | c.1371C>G p.Y457* | Nonsense Mutation (SNP) | VAF 166/433 reads (38%) | called by muse, mutect2, varscan2
- NUP210L | c.342G>A p.V114= | Splice Region (SNP) | VAF 45/118 reads (38%) | called by muse, mutect2, varscan2
- PDGFD | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TMEM221 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2
- TMPRSS7 | c.1568C>T p.P523L (on ENST00000452346; = p.P397L on NM_001042575.2) | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TTN | c.25096C>A p.L8366I (on ENST00000591111; = p.L7439I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/176 reads (39%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- URB1 | c.5671G>A p.A1891T | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- VPS8 | c.680dup p.D227Efs*29 (on ENST00000625842 / NM_001349294.1; = p.D225Efs*29 on NM_015303.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 63/191 reads (33%) | called by mutect2, pindel, varscan2
- ZNF366 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF638 | c.1308T>G p.S436R | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ZRSR2 | c.353A>T p.E118V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTL9 | c.354C>T p.I118= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs782337387, COSV100185101; called by muse, mutect2, varscan2
- CFAP43 | c.4164G>A p.K1388= | Silent (SNP) | VAF 43/60 reads (72%) | called by muse, mutect2, varscan2
- CYLD | c.675C>T p.V225= | Silent (SNP) | VAF 54/245 reads (22%) | catalogued as rs184354524, COSV61093625; called by muse, mutect2, varscan2
- DNAH3 | c.8601G>A p.P2867= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs771608383; called by muse, mutect2, varscan2
- FTO | c.1386A>G p.R462= | Silent (SNP) | VAF 89/317 reads (28%) | called by muse, mutect2, varscan2
- HTR2C | c.630C>T p.N210= | Silent (SNP) | VAF 164/174 reads (94%) | catalogued as rs782644122, COSV52222042; called by muse, mutect2, varscan2
- IDE | c.2691A>G p.P897= | Silent (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- IRF3 | c.303C>T p.H101= | Silent (SNP) | VAF 54/297 reads (18%) | catalogued as rs372990308; called by muse, mutect2, varscan2
- KCNG1 | c.1272G>A p.T424= | Silent (SNP) | VAF 72/195 reads (37%) | catalogued as rs1243814356, COSV65369401; called by muse, mutect2, varscan2
- KRT78 | c.1146G>A p.L382= | Silent (SNP) | VAF 141/359 reads (39%) | called by muse, mutect2, varscan2
- MAGEC1 | c.132C>T p.S44= | Silent (SNP) | VAF 203/234 reads (87%) | catalogued as rs1277582517, COSV53581509; called by muse, mutect2, varscan2
- MYH13 | c.2373C>T p.S791= | Silent (SNP) | VAF 117/284 reads (41%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1761C>T p.N587= | Silent (SNP) | VAF 140/379 reads (37%) | catalogued as rs756682784, COSV53937153; called by muse, mutect2, varscan2
- POTEE | c.3051C>A p.I1017= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs1205123168; called by mutect2, varscan2
- RCAN2 | c.66C>T p.V22= | Silent (SNP) | VAF 20/192 reads (10%) | catalogued as COSV57817134; called by muse, mutect2
- TLN2 | c.5724G>A p.A1908= | Silent (SNP) | VAF 15/196 reads (8%) | catalogued as rs754878427; called by muse, mutect2
- TMEM132C | c.789G>A p.T263= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as rs997289387, COSV70662374; called by muse, mutect2, varscan2
- TMTC2 | c.1783C>T p.L595= | Silent (SNP) | VAF 128/335 reads (38%) | called by muse, mutect2, varscan2
- TRPC7 | c.741C>T p.N247= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100726000; called by muse, varscan2
- ABCC13 | n.3851G>T | RNA (SNP) | VAF 75/182 reads (41%) | called by muse, mutect2, varscan2
- AP005119.2 | chr18:1358757 G>T | 3'Flank (SNP) | VAF 49/153 reads (32%) | called by muse, mutect2, varscan2
- BMPER | c.134-17T>C | Intron (SNP) | VAF 96/347 reads (28%) | catalogued as rs542452381, COSV51819967, COSV99779733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3P1 | n.3106G>A | RNA (SNP) | VAF 50/314 reads (16%) | catalogued as rs1198811303; called by muse, mutect2, varscan2
- DST | c.4297-4588G>A | Intron (SNP) | VAF 86/226 reads (38%) | catalogued as rs370912424; ClinVar: likely benign; called by muse, mutect2, varscan2
- GUSBP1 | n.180-6579C>T | Intron (SNP) | VAF 22/850 reads (3%) | called by muse, mutect2
- MPP4 | c.1051+42G>A | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18339110 C>T | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs1247301377; called by mutect2, varscan2
- PLG | c.185+25C>T | Intron (SNP) | VAF 56/131 reads (43%) | catalogued as rs376903431; called by muse, mutect2
- PRKAG1 | c.9+1531_9+1532dup | Intron (INS) | VAF 90/284 reads (32%) | called by mutect2, pindel, varscan2
- RAN | c.248-474C>T | Intron (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- RBFOX1 | c.1072-12G>A | Intron (SNP) | VAF 66/181 reads (36%) | called by muse, mutect2, varscan2
- TM7SF2 | c.-41_-38del | 5'UTR (DEL) | VAF 26/135 reads (19%) | catalogued as rs750391341; called by pindel, varscan2
- TMCO6 | c.198+12A>T | Intron (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- TTC39B | c.-29C>G | 5'UTR (SNP) | VAF 30/147 reads (20%) | catalogued as rs1290840312; called by muse, mutect2, varscan2
- ZNF609 | c.747+41C>T | Intron (SNP) | VAF 70/164 reads (43%) | catalogued as rs780503586; called by muse, mutect2, varscan2
- ZSCAN18 | c.49+10G>A | Intron (SNP) | VAF 72/246 reads (29%) | called by muse, mutect2, varscan2
